Somatic mutation profile of tumor specimen TCGA-FS-A1YX-06A (aliquot TCGA-FS-A1YX-06A-11D-A197-08) from TCGA case TCGA-FS-A1YX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.1 years (15,760 days).
Specimen TCGA-FS-A1YX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11bd7f27-b09f-4875-be62-b5842ad56df4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1YX-10A (Blood Derived Normal), aliquot TCGA-FS-A1YX-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb71ec21-74e7-45f8-b0a9-c77af319b273

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, In Frame Del 2, RNA 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM20 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56455839; called by muse, mutect2, varscan2
- ADGRG4 | c.1690T>A p.S564T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV54962564; called by muse, mutect2, varscan2
- DCDC1 | c.3133G>A p.A1045T (on ENST00000597505 / NM_001367979.1; = p.A152T on NM_020869.3) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV60306869, COSV60309753; called by muse, mutect2, varscan2
- FAT3 | c.4448A>C p.E1483A | Missense Mutation (SNP) | VAF 135/330 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.174); catalogued as COSV53148722; called by muse, mutect2, varscan2
- FRMPD3 | c.3046G>A p.G1016S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV99346708; called by muse, mutect2
- GABRE | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV100944270, COSV64820614; called by muse, mutect2, varscan2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2, varscan2
- HJURP | c.1593C>A p.H531Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV64979137; called by muse, mutect2, varscan2
- KRT10 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV54090792; called by muse, mutect2, varscan2
- MAP1B | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57103217; called by muse, mutect2
- MYO3A | c.3903G>A p.M1301I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99780590; called by muse, mutect2, varscan2
- MYO3A | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV56349678, COSV99780593; called by muse, mutect2, varscan2
- NLRP13 | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV61623250; called by muse, mutect2, varscan2
- OR2B11 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs868431495, COSV59510945; called by muse, mutect2, varscan2
- PCDHB5 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1487998791, COSV50660344, COSV50673541; called by muse, mutect2, varscan2
- RETREG3 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52222064; called by muse, mutect2, varscan2
- RYR1 | c.8953C>T p.R2985* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as rs1381679767, CM136217, COSV62093354; called by muse, mutect2, varscan2
- SC5D | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs118099079, COSV50613395; called by muse, mutect2, varscan2
- TMEM139 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV60082965; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2299A>C p.S767R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ARFGEF1 | c.2908_2910del p.T970del | In Frame Del (DEL) | VAF 27/98 reads (28%) | called by mutect2, pindel, varscan2
- C5orf38 | c.204_209del p.F68_V69del | In Frame Del (DEL) | VAF 29/107 reads (27%) | called by mutect2, pindel, varscan2
- DLG4 | c.1592-14_1592-1del p.X531_splice (on ENST00000399506 / NM_001321075.3; = p.X574_splice on NM_001365.4) | Splice Site (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- FRMPD3 | c.3045G>A p.R1015= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99346705; called by muse, mutect2
- MBTD1 | c.1074G>A p.K358= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV64503966; called by muse, mutect2, varscan2
- SNX16 | c.888G>A p.V296= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100629628, COSV62036081; called by muse, mutect2, varscan2
- TGIF2LX | c.327C>A p.L109= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV52214751; called by mutect2, varscan2
- C7orf65 | n.312dup | RNA (INS) | VAF 30/88 reads (34%) | called by mutect2, pindel, varscan2
- SERPINA13P | n.1134C>A | RNA (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
